Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A912, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Barretos Cancer Hospital, specimen TCGA-YU-A912-01A (Primary Tumor).

Collect date: :
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

1. "Pelvic mass (left testis)":
- Classic seminoma;
- Angiolymphatic and perineural invasions not observed;
- Surgical margin uninvolved by neoplasia.

Note: See immunohistochemistry exam.

Immunohistochemistry exam:

Morphologic aspects associated to immunohistochemistry profile are compatible with seminoma diagnosis.

ICD-O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
9/3/14

Criteria	hw 11/5/13	Yes	No
IHPAA Discrepancy			✓

Source: NCI Genomic Data Commons file dab54df2-0d23-4979-bb5e-da0f8fe33cc1 (TCGA-YU-A912.A472F58A-0BAD-4637-A747-1702913084BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).